Somatic mutation profile of tumor specimen TCGA-A2-A0YK-01A (aliquot TCGA-A2-A0YK-01A-22D-A117-09) from TCGA case TCGA-A2-A0YK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.9 years (22,625 days).
Specimen TCGA-A2-A0YK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9fd2038-4b38-45bd-8ef8-4cd82206ea87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YK-10A (Blood Derived Normal), aliquot TCGA-A2-A0YK-10A-01D-A117-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cad7a22f-aec4-4912-9f05-8686d8c38743

The open-access MAF lists 375 somatic variants for this specimen: 271 protein-altering or splice-affecting, 97 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 97, Nonsense Mutation 27, Splice Site 4, Splice Region 3, Intron 2, 5'Flank 2, Nonstop Mutation 1, 3'Flank 1, 5'UTR 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | hotspot (GDC flag); catalogued as rs587783047, CM980317, COSV55728388, COSV55734769, COSV55741582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC008397.2 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as COSV53206284, COSV99441114, COSV99442346; called by muse, mutect2
- ACTR6 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99498462; called by muse, mutect2
- AHNAK | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as COSV99945339; called by muse, mutect2, varscan2
- AHNAK | c.4018G>C p.D1340H | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57235258; called by muse, mutect2, varscan2
- AHNAK | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV57235271; called by muse, mutect2, varscan2
- AIFM2 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV57161145; called by muse, mutect2, varscan2
- AKAP11 | c.4930C>G p.L1644V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV99213415; called by muse, mutect2
- AKR1C2 | c.580C>G p.H194D | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66334665; called by muse, mutect2, varscan2
- ANKRD26 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV65779028; called by muse, mutect2, varscan2
- AQP6 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59645840; called by muse, mutect2
- ARHGAP29 | c.2078C>G p.S693* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV53118222; called by muse, mutect2, varscan2
- ARHGAP31 | c.537C>T p.L179= | Splice Region (SNP) | VAF 11/75 reads (15%) | catalogued as COSV51800606; called by muse, mutect2, varscan2
- ARHGEF7 | c.1567C>T p.Q523* (on ENST00000375741 / NM_001113511.2; = p.Q345* on NM_003899.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 29/243 reads (12%) | catalogued as COSV54553724; called by muse, mutect2, varscan2
- ARID1B | c.3442G>C p.E1148Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as CM1314076, COSV99266777; called by muse, mutect2
- ARMC10 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as rs974342956, COSV58523086; called by muse, mutect2, varscan2
- ARMH4 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV50778077; called by muse, mutect2, varscan2
- ASB15 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99306124; called by muse, mutect2
- ASH2L | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.572); catalogued as COSV99166912; called by muse, mutect2
- ASXL3 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52483155; called by muse, mutect2, varscan2
- ATM | c.8158G>A p.D2720N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as rs876659942, CM160106, COSV53748743, COSV53750700, COSV53766226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRN | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV53535900; called by muse, mutect2, varscan2
- B3GALT4 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.772); catalogued as COSV101005541; called by muse, mutect2
- BCAS1 | c.1417-1G>C p.X473_splice | Splice Site (SNP) | VAF 25/157 reads (16%) | catalogued as COSV101006002; called by muse, mutect2
- BIRC6 | c.11476C>G p.L3826V | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.29); catalogued as COSV101427773; called by muse, mutect2
- BIVM-ERCC5 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); catalogued as COSV99958507; called by muse, mutect2, varscan2
- BMI1 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64959816; called by muse, mutect2, varscan2
- C1orf21 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as COSV99333946; called by muse, mutect2, varscan2
- C7 | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100495315, COSV57481890; called by muse, mutect2
- CACNA1F | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs782399050, COSV100544314, COSV59906506; called by muse, mutect2
- CACNA2D2 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56570244; called by muse, mutect2, varscan2
- CAPN10 | c.356G>A p.W119* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV99549886; called by muse, mutect2, varscan2
- CAPRIN2 | c.588G>C p.K196N | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV99195405, COSV99195547; called by muse, mutect2, varscan2
- CARMIL3 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100549170; called by muse, mutect2
- CC2D1A | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528199; called by muse, mutect2, varscan2
- CCDC125 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV67289109; called by muse, mutect2
- CCDC185 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs773410324, COSV64820553; called by mutect2, varscan2
- CCN2 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1464236501, COSV63466633, COSV63466764; called by muse, mutect2, varscan2
- CCT8 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as COSV54506582; called by muse, mutect2, varscan2
- CDC37 | c.650A>C p.Q217P | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99705646; called by muse, mutect2, varscan2
- CDH10 | c.823C>T p.H275Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.826); catalogued as COSV100052573, COSV52602317; called by muse, mutect2, varscan2
- CDH19 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50983607; called by muse, mutect2, varscan2
- CECR2 | c.3931G>C p.E1311Q (on ENST00000342247 / NM_001290047.2; = p.E1127Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99376865; called by muse, mutect2, varscan2
- CEP89 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99992997; called by muse, mutect2
- CFAP54 | c.6415T>C p.Y2139H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1258120969, COSV61576145; called by muse, mutect2, varscan2
- CFAP74 | c.4384G>C p.E1462Q | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.686); catalogued as COSV60588137; called by muse, mutect2, varscan2
- CFAP91 | c.2016G>C p.E672D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV99846786; called by muse, mutect2
- CHD4 | c.2419G>A p.E807K (on ENST00000357008 / NM_001363606.2; = p.E820K on NM_001273.5) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58913075; called by muse, mutect2, varscan2
- CHFR | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99904874; called by muse, mutect2
- CHRNG | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs201857172, COSV101263886, COSV67315994; called by mutect2, varscan2
- CKAP5 | c.3470C>G p.S1157C | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56375627; called by muse, mutect2, varscan2
- COL11A1 | c.3193G>A p.A1065T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV62202095; called by muse, mutect2, varscan2
- COL5A2 | c.3748G>C p.E1250Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.616); catalogued as COSV100879964; called by muse, mutect2
- COPS6 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 17/121 reads (14%) | catalogued as COSV57999718; called by muse, mutect2, varscan2
- CORO7 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV52034814; called by muse, mutect2, varscan2
- CPLX4 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs745727054, COSV55315280; called by muse, mutect2, varscan2
- CPSF7 | c.505G>A p.E169K (on ENST00000394888 / NM_001136040.4; = p.E212K on NM_024811.4) | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV61213291; called by muse, mutect2, varscan2
- CSMD1 | c.5551G>A p.E1851K (on ENST00000520002; = p.E1850K on NM_033225.6) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59286044; called by muse, mutect2, varscan2
- CTSS | c.276G>T p.M92I | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100934890; called by muse, mutect2
- CUL3 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV100023686, COSV100024408; called by muse, mutect2
- CUL4B | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs750144966, COSV60691821; called by muse, mutect2, varscan2
- CXorf58 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as COSV64858959; called by muse, mutect2, varscan2
- CYP3A43 | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55938755; called by muse, mutect2, varscan2
- DAAM1 | c.775-1G>C p.X259_splice | Splice Site (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100658087; called by muse, mutect2
- DCLRE1C | c.1310G>C p.R437T (on ENST00000378278 / NM_001350965.2; = p.R322T on NM_022487.4) | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV57955940; called by muse, mutect2, varscan2
- DDHD2 | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV101240476; called by muse, mutect2
- DENND3 | c.887C>G p.S296C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); catalogued as COSV52807965, COSV52808596; called by muse, mutect2, varscan2
- DHX34 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs928386903, COSV60899344; called by muse, mutect2, varscan2
- DIO3 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100832021; called by muse, mutect2
- DLG5 | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs200259340; called by muse, mutect2, varscan2
- DMGDH | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV99668381, COSV99668399; called by muse, mutect2
- DMXL2 | c.5858C>G p.S1953* | Nonsense Mutation (SNP) | VAF 15/180 reads (8%) | catalogued as COSV99195923; called by muse, mutect2
- DOCK1 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99726519; called by muse, mutect2
- DYNC2LI1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV53185832; called by muse, mutect2, varscan2
- ECEL1 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.335); catalogued as COSV58814678; called by muse, mutect2, varscan2
- EIF4B | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as COSV50401978, COSV50403584; called by muse, mutect2
- EMSY | c.2856G>C p.Q952H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV58263233, COSV58267045; called by muse, mutect2, varscan2
- ENO2 | c.1140C>A p.F380L | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1555142183, COSV99980128; called by muse, mutect2
- EPHB6 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV63894162; called by muse, mutect2, varscan2
- ERC1 | c.2334G>C p.K778N (on ENST00000360905 / NM_178040.4; = p.K750N on NM_178039.4) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100705589; called by muse, mutect2
- ESPL1 | c.1401C>A p.F467L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as COSV57757811, COSV57764341; called by muse, mutect2, varscan2
- ETS2 | c.1236G>C p.M412I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62874857; called by muse, mutect2, varscan2
- EXOC3 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100155020; called by muse, mutect2
- F8 | c.1394C>T p.S465L | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs1557281947, CM010849, COSV100811224; called by muse, mutect2
- FADS3 | c.1181G>C p.R394T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99605063; called by muse, mutect2
- FAM13A | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99982778; called by muse, mutect2
- FAM161B | c.1343G>C p.R448T (on ENST00000651776; = p.R385T on NM_152445.3) | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV54105197; called by muse, mutect2, varscan2
- FAM76B | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57690118, COSV57691033; called by muse, mutect2
- FAR1 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 13/170 reads (8%) | catalogued as COSV100701492; called by muse, mutect2
- FARS2 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99212886; called by muse, mutect2
- FEZ1 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV54032534; called by muse, mutect2, varscan2
- FIGN | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as COSV100291386; called by muse, mutect2
- FNBP1L | c.390G>C p.W130C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53097232; called by muse, mutect2, varscan2
- FRMPD1 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs761022584, COSV66699257; called by muse, mutect2, varscan2
- FUT8 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV100650982; called by muse, mutect2, varscan2
- G3BP1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV62365957; called by muse, mutect2, varscan2
- G3BP2 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62977962; called by muse, mutect2, varscan2
- GEMIN5 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV99593555; called by muse, mutect2
- GORASP2 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52204376; called by muse, mutect2, varscan2
- GPR6 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51574295; called by muse, mutect2, varscan2
- GRIK1 | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs769191901, COSV58736070; called by muse, mutect2, varscan2
- HDAC8 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65240366; called by muse, mutect2, varscan2
- HECTD1 | c.6715G>A p.E2239K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as COSV101237294; called by muse, mutect2, varscan2
- HECW1 | c.4015G>C p.E1339Q | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101222708; called by muse, mutect2
- HIRA | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54281190; called by muse, mutect2, varscan2
- HLTF | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV59501934; called by muse, mutect2
- HMGCR | c.1062C>G p.I354M | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs144482710; called by muse, mutect2, varscan2
- HRH3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.112); catalogued as rs200732003; called by mutect2, varscan2
- HUNK | c.1862C>G p.S621C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.993); catalogued as COSV99527931; called by muse, mutect2, varscan2
- HYDIN | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99861772; called by muse, mutect2
- IL13RA1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100861682; called by muse, mutect2
- INTU | c.1575G>C p.L525F | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV58873526, COSV58875769; called by muse, mutect2, varscan2
- IPO5 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs1279488903, COSV55160843; called by muse, varscan2
- IQGAP3 | c.4858C>T p.L1620F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100752031; called by muse, mutect2
- IQGAP3 | c.4271C>T p.S1424L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV63255314; called by muse, mutect2, varscan2
- IRAK3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV99705846; called by muse, mutect2
- IRF9 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.936); catalogued as COSV60702716, COSV60704258; called by muse, mutect2, varscan2
- KCNK7 | c.807C>G p.F269L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV58422266; called by muse, mutect2, varscan2
- KIAA0319 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV100985140; called by muse, mutect2
- KIAA1143 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as COSV56089478, COSV99941514; called by muse, mutect2, varscan2
- KIAA1614 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV100851148; called by muse, mutect2
- KIF13A | c.2915A>G p.H972R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52468917; called by muse, mutect2, varscan2
- KIF5C | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV101276086; called by muse, mutect2
- KIZ | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99851803; called by muse, mutect2
- KRIT1 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.804); catalogued as rs1170498982, CD104928, COSV60670896; called by muse, mutect2
- LATS1 | c.2259G>C p.E753D | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99485140; called by muse, mutect2
- LDB1 | c.301G>C p.D101H (on ENST00000425280 / NM_001321612.2; = p.D65H on NM_003893.5) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100756308, COSV63288863; called by muse, mutect2
- LEXM | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.804); catalogued as COSV64024525; called by muse, mutect2, varscan2
- LMOD1 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100939075; called by muse, mutect2, varscan2
- LRFN4 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs371172656; called by muse, mutect2, varscan2
- LRRC23 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV50400254; called by muse, mutect2, varscan2
- LRRCC1 | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64486392; called by muse, mutect2, varscan2
- LRRFIP2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV60871207; called by muse, mutect2, varscan2
- MAGEA4 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.622); catalogued as COSV99367256; called by muse, mutect2
- MAP3K1 | c.3230C>G p.S1077* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV68121525; called by muse, mutect2, varscan2
- MAST2 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs944773245, COSV63621830; called by muse, mutect2, varscan2
- MBD5 | c.1173G>C p.M391I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV68698964; called by muse, mutect2, varscan2
- METTL18 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99609316; called by muse, mutect2
- MFF | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs908899939, COSV58827001; called by muse, mutect2, varscan2
- MID2 | c.1827C>G p.Y609* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV53315235, COSV99464759; called by muse, mutect2, varscan2
- MMS22L | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV51528179; called by muse, mutect2, varscan2
- MROH2B | c.3938G>A p.W1313* | Nonsense Mutation (SNP) | VAF 18/187 reads (10%) | catalogued as COSV101270452; called by muse, mutect2
- MRPS35 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV99317287; called by muse, mutect2
- MSL3 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.984); catalogued as COSV56496552; called by muse, mutect2, varscan2
- MTBP | c.1235G>T p.R412I | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as rs1350723831, COSV100011754; called by muse, mutect2
- MTHFD2 | c.582G>C p.K194N | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99902882, COSV99903088; called by muse, mutect2
- MUC20 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs751917792, COSV100290874; called by muse, mutect2, varscan2
- MYH6 | c.5026G>A p.V1676M | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs773755388, COSV62455549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD8 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51662215; called by muse, mutect2, varscan2
- NF1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.732); catalogued as CM001254, COSV62215915, COSV62225469; called by muse, mutect2, varscan2
- NFAT5 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.309); catalogued as COSV63033928; called by muse, mutect2, varscan2
- NFATC2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65362222; called by muse, mutect2
- NFKBIZ | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as COSV100396892, COSV58202035; called by muse, mutect2
- NLN | c.1734G>C p.Q578H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101114093; called by muse, mutect2
- NOL11 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53525309; called by muse, mutect2
- NR2E3 | c.1134G>C p.L378F | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58910603; called by muse, mutect2, varscan2
- NSD3 | c.2918G>A p.W973* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100394868; called by muse, mutect2
- OR7A5 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100457592, COSV59234504; called by muse, mutect2
- OR9K2 | c.502C>G p.Q168E (on ENST00000305377; = p.Q146E on NM_001005243.1) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as COSV59533760; called by muse, mutect2, varscan2
- OSBPL5 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs1351315188, COSV99719960; called by muse, mutect2, varscan2
- OSBPL8 | c.2538-1G>A p.X846_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | catalogued as COSV99674408; called by muse, mutect2
- OTOGL | c.5722G>C p.E1908Q (on ENST00000547103; = p.E1899Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV100086566; called by muse, mutect2, varscan2
- PAK2 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100505803; called by muse, mutect2
- PAQR3 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55011972, COSV55012544; called by muse, mutect2, varscan2
- PBXIP1 | c.653C>A p.S218* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as COSV100869989; called by muse, mutect2
- PCDHB14 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.183); catalogued as COSV53390954; called by muse, mutect2, varscan2
- PCDHGA10 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99529418; called by muse, mutect2
- PCYT1B | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as COSV100770432; called by muse, mutect2
- PDE6A | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV54929585; called by muse, mutect2
- PER2 | c.505G>C p.D169H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV54528992; called by muse, mutect2, varscan2
- PEX1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV50425606; called by muse, mutect2, varscan2
- PHF20L1 | c.2449C>G p.Q817E | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55195030, COSV99620201; called by muse, mutect2
- PI4KA | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55417851; called by muse, mutect2
- PIH1D2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs782581362, COSV99734375; called by mutect2, varscan2
- PITPNM1 | c.1933C>G p.Q645E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.093); catalogued as COSV62707679, COSV62710354; called by muse, mutect2, varscan2
- PLCB4 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53822254; called by muse, mutect2, varscan2
- PLCH2 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs969425551, COSV99615434; called by muse, mutect2
- POLR3F | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs1038842562, COSV101112277; called by muse, mutect2
- POMT2 | c.1333-1G>C p.X445_splice | Splice Site (SNP) | VAF 8/53 reads (15%) | catalogued as COSV55074498, COSV55074635; called by muse, mutect2, varscan2
- POSTN | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753646323, COSV101123239; called by muse, mutect2, varscan2
- PPA1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV64684625; called by muse, mutect2, varscan2
- PPM1F | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as rs1200553660, COSV99601230; called by muse, mutect2
- PPP1R12A | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 49/458 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as COSV54115224; called by muse, mutect2, varscan2
- PPP1R8 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV52581481; called by muse, mutect2, varscan2
- PPP1R9A | c.3258G>T p.K1086N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV99194542; called by muse, mutect2
- PRKD3 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as COSV52218758, COSV52220452; called by muse, mutect2, varscan2
- PROX1 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as COSV54780249, COSV54784932; called by muse, mutect2
- PTPN7 | c.784G>A p.E262K (on ENST00000495688; = p.E301K on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV58315270; called by muse, mutect2, varscan2
- PTPRK | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 26/252 reads (10%) | catalogued as COSV63909516; called by muse, mutect2, varscan2
- PUM1 | c.3560G>C p.*1187Sext*71 | Nonstop Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as COSV57092523, COSV99928886; called by muse, mutect2, varscan2
- PXDNL | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100680871; called by muse, mutect2
- PXK | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV100243802; called by muse, mutect2
- QRICH1 | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100676807, COSV62617980; called by muse, mutect2, varscan2
- RADX | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100998726; called by muse, mutect2
- RAI2 | c.71G>C p.R24T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100518137; called by muse, mutect2
- RALGAPB | c.4156G>C p.E1386Q | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV53444602; called by muse, mutect2, varscan2
- RAPGEF6 | c.4048C>T p.Q1350* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99725023; called by muse, mutect2, varscan2
- RASGRP2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV100818124; called by muse, mutect2, varscan2
- RCSD1 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63261546; called by muse, mutect2, varscan2
- REC8 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100269036, COSV61018826; called by muse, mutect2, varscan2
- RGS12 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747626425, COSV60682612; called by muse, mutect2, varscan2
- RHOQ | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99475608; called by muse, mutect2
- SDE2 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99682436; called by muse, mutect2
- SETD4 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as COSV59772340; called by muse, mutect2, varscan2
- SETX | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV99808667; called by muse, mutect2
- SHE | c.594C>T p.V198= | Splice Region (SNP) | VAF 24/175 reads (14%) | catalogued as COSV59073520; called by muse, mutect2, varscan2
- SIN3A | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | catalogued as COSV100845015; called by muse, mutect2
- SIRT2 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430999088, COSV99979177; called by muse, mutect2, varscan2
- SLC17A6 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV54142948; called by muse, mutect2, varscan2
- SLC1A6 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55674969; called by muse, mutect2, varscan2
- SLC26A1 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV56107473; called by mutect2, varscan2
- SLC2A4RG | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.949); catalogued as COSV99828709; called by muse, mutect2
- SLFN5 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV55484317; called by muse, mutect2, varscan2
- SLITRK3 | c.1816G>T p.E606* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99578378; called by mutect2, varscan2
- SMYD3 | c.705C>T p.L235= (on ENST00000490107 / NM_001375962.1; = p.L176= on NM_022743.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 13/90 reads (14%) | catalogued as rs759928395, COSV63630138; called by muse, mutect2, varscan2
- SNRK | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56071656, COSV99939030; called by muse, mutect2, varscan2
- SNX1 | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV99975827; called by muse, mutect2
- SNX27 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.802); catalogued as COSV64327941; called by muse, mutect2, varscan2
- SPAG6 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV100509906, COSV57622044; called by muse, mutect2
- SPICE1 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs751745421, COSV99870791; called by muse, mutect2, varscan2
- ST18 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52513190, COSV99035461; called by muse, mutect2, varscan2
- SUSD2 | c.2032G>C p.E678Q | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.598); catalogued as COSV64205656; called by muse, mutect2, varscan2
- SYNPO2 | c.3222C>G p.F1074L | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100204754, COSV61106280; called by muse, mutect2, varscan2
- SYT2 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV66142636, COSV66143565; called by muse, mutect2, varscan2
- TAF5 | c.2164G>C p.D722H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100428189; called by muse, mutect2
- TCEAL3 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 46/522 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV99685197; called by muse, mutect2
- TCP11 | c.1336C>A p.L446I (on ENST00000512012; = p.L384I on NM_018679.5) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55136712; called by muse, mutect2, varscan2
- TFDP1 | c.764C>G p.S255* | Nonsense Mutation (SNP) | VAF 11/128 reads (9%) | catalogued as COSV100945696, COSV100946063; called by muse, mutect2
- TGM5 | c.2070G>T p.K690N (on ENST00000220420 / NM_201631.4; = p.K608N on NM_004245.4) | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55012845; called by muse, mutect2, varscan2
- TLN1 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV59204651; called by muse, mutect2
- TLR4 | c.1596C>G p.F532L (on ENST00000355622 / NM_138554.5; = p.F492L on NM_003266.4) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs34953464, COSV62924531; called by muse, mutect2
- TMED7 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV56696614; called by muse, mutect2, varscan2
- TREML4 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100422797; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100708837; called by muse, mutect2
- TSG101 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99323672; called by muse, mutect2
- TSHR | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as rs747590314, COSV53316694; called by muse, mutect2, varscan2
- TSPEAR | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59953697, COSV59968565; called by muse, mutect2, varscan2
- TTN | c.18811G>C p.D6271H (on ENST00000591111; = p.D5344H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | PolyPhen possibly damaging (0.875); catalogued as COSV60410735, COSV60417168; called by muse, mutect2, varscan2
- TUBGCP6 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184438103, COSV99352042; called by muse, mutect2, varscan2
- UBE2D2 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as COSV54080918, COSV99551398; called by muse, mutect2, varscan2
- UBR4 | c.15224G>C p.G5075A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.099); catalogued as COSV100920126; called by muse, mutect2
- UPF3B | c.1186G>C p.E396Q (on ENST00000276201 / NM_080632.3; = p.E383Q on NM_023010.3) | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV52230024; called by muse, mutect2
- USH2A | c.3066C>G p.F1022L | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.699); catalogued as COSV100232471, COSV56453516; called by muse, mutect2, varscan2
- USP1 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374962; called by muse, mutect2
- UST | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.027); catalogued as COSV66551101; called by muse, mutect2, varscan2
- UTRN | c.2422G>C p.D808H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.352); catalogued as COSV100839466; called by muse, mutect2, varscan2
- UTRN | c.8662G>A p.E2888K | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100838158, COSV62313251; called by muse, mutect2, varscan2
- VPS13C | c.4351G>A p.E1451K (on ENST00000644861 / NM_020821.3; = p.E1408K on NM_017684.5) | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV51426699, COSV99826817; called by muse, mutect2
- VSTM4 | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as COSV60530382; called by muse, mutect2, varscan2
- WARS2 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV52483541; called by muse, mutect2, varscan2
- WDR47 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63060382; called by muse, mutect2, varscan2
- XRN1 | c.3854G>C p.R1285T | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.057); catalogued as COSV99377109; called by muse, mutect2, varscan2
- YTHDF1 | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV64833864, COSV64834056; called by muse, mutect2, varscan2
- ZBED8 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV101283458; called by muse, mutect2
- ZBTB34 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 11/142 reads (8%) | catalogued as COSV100043515; called by muse, mutect2
- ZC3H12C | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1473251434, COSV99584580; called by muse, mutect2
- ZCCHC17 | c.238A>T p.R80* | Nonsense Mutation (SNP) | VAF 21/146 reads (14%) | catalogued as COSV60004139; called by muse, mutect2, varscan2
- ZDHHC17 | c.1758C>G p.F586L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58354722; called by muse, mutect2, varscan2
- ZKSCAN7 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.404); catalogued as COSV99837395; called by muse, mutect2
- ZNF165 | c.1107G>C p.E369D | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66103094; called by muse, mutect2
- ZNF438 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs35170728; called by muse, mutect2, varscan2
- ZNF518B | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1428715187, COSV100456535; called by muse, mutect2
- ZNF662 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV60243399; called by muse, mutect2, varscan2
- ZNF7 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100295611; called by muse, mutect2
- ZNF778 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs745710031, COSV60603191; called by muse, mutect2, varscan2
- ZNF836 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100440564; called by muse, mutect2
- ACACA | c.3673C>T p.H1225Y | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLL2 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- VN1R5 | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 25/238 reads (11%) | called by muse, mutect2, varscan2
- ZMYM2 | c.328_337del p.K110* | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- ABCB8 | c.948C>T p.L316= (on ENST00000297504 / NM_001282291.2; = p.L299= on NM_007188.5) | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs888355948, COSV52511672; called by muse, mutect2, varscan2
- ABCC10 | c.1683C>G p.L561= (on ENST00000372530 / NM_001198934.2; = p.L518= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV55095201; called by muse, mutect2, varscan2
- AC004922.1 | c.648G>C p.G216= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV53559774; called by muse, mutect2, varscan2
- ACP7 | c.162C>T p.V54= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1161727783, COSV100488410; called by muse, mutect2
- ADGRE3 | c.810G>A p.V270= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV99505749; called by muse, mutect2
- ADGRG5 | c.882G>A p.L294= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs988334195, COSV61084970; called by muse, mutect2, varscan2
- AHNAK | c.2481G>A p.L827= | Silent (SNP) | VAF 16/171 reads (9%) | catalogued as COSV99945342; called by muse, mutect2
- AL645922.1 | c.2784T>C p.Y928= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs539673510, COSV54963291; called by muse, mutect2
- ALMS1 | c.3123G>A p.E1041= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100040964; called by muse, mutect2
- ANKRD11 | c.981C>T p.L327= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV56374894; called by muse, mutect2, varscan2
- AP002748.5 | c.411G>C p.R137= | Silent (SNP) | VAF 9/157 reads (6%) | catalogued as COSV100567664; called by muse, mutect2
- AP2B1 | c.1842C>T p.N614= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV52004476; called by muse, mutect2, varscan2
- AP3B1 | c.102C>T p.F34= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1460618374, COSV54884964, COSV54895344; called by muse, mutect2, varscan2
- ASAP3 | c.594C>G p.L198= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as COSV60878173; called by muse, mutect2, varscan2
- ATM | c.7365G>A p.L2455= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as COSV53781837; called by muse, mutect2, varscan2
- C1orf35 | c.357G>A p.L119= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2
- CAB39L | c.438G>T p.L146= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV100759479; called by muse, mutect2
- CATSPERE | c.1131G>A p.L377= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100834867; called by muse, mutect2
- CCDC65 | c.252C>T p.L84= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV57198451; called by muse, mutect2, varscan2
- CHRNA9 | c.735C>T p.L245= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100038787; called by muse, mutect2, varscan2
- CNBD2 | c.837C>T p.F279= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100839031; called by muse, mutect2
- CNGB1 | c.2271G>A p.V757= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99201371; called by muse, mutect2
- CPA3 | c.1041C>A p.I347= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV56047969; called by muse, mutect2, varscan2
- CYB5D1 | c.351G>A p.G117= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99640662; called by muse, mutect2, varscan2
- CYP11A1 | c.1341C>T p.I447= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as COSV51435506, COSV99165909; called by muse, mutect2, varscan2
- CYP4F22 | c.57C>T p.F19= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV99512472; called by muse, mutect2
- DDX3X | c.1248G>A p.Q416= (on ENST00000399959; = p.Q417= on NM_001356.5) | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV67863903; called by muse, mutect2, varscan2
- DENND2B | c.2487C>T p.F829= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV58208571; called by muse, mutect2, varscan2
- DPYSL5 | c.885C>T p.V295= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99981693; called by muse, mutect2
- ECHDC3 | c.273G>C p.L91= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV64868058; called by muse, mutect2, varscan2
- ENPP5 | c.555C>G p.L185= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100040222, COSV57910335; called by muse, mutect2
- EOLA2 | c.105G>A p.R35= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV100778027; called by mutect2, varscan2
- EPRS1 | c.153G>T p.V51= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100859288; called by muse, mutect2
- FAM214A | c.1884C>T p.F628= | Silent (SNP) | VAF 16/194 reads (8%) | catalogued as COSV99957548; called by muse, mutect2
- FERMT3 | c.1038C>T p.L346= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV54177603, COSV99656251; called by muse, mutect2
- FGD5 | c.3588C>T p.D1196= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1489564950, COSV53254890; called by mutect2, varscan2
- GALR1 | c.258C>G p.L86= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV55317587; called by muse, mutect2, varscan2
- GBA3 | c.172C>T p.L58= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as rs747696603, COSV101545462; called by muse, mutect2
- GGN | c.1098C>T p.F366= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV53059490; called by muse, mutect2, varscan2
- GLIS3 | c.1110C>T p.H370= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs904829456, COSV60937756; called by muse, mutect2, varscan2
- GMPR | c.936G>T p.L312= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99439703; called by muse, mutect2, varscan2
- GNAT2 | c.645C>T p.F215= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs534677249, COSV63554960; called by mutect2, varscan2
- GOLPH3 | c.582C>T p.F194= | Silent (SNP) | VAF 16/217 reads (7%) | catalogued as COSV99416968; called by muse, mutect2
- GPHN | c.444G>A p.K148= | Silent (SNP) | VAF 19/240 reads (8%) | catalogued as COSV100015190; called by muse, mutect2
- GPR161 | c.604C>T p.L202= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs1180427349, COSV54793113, COSV99606309; called by muse, mutect2
- H2BC21 | c.186C>T p.I62= | Silent (SNP) | VAF 20/238 reads (8%) | catalogued as COSV100479663; called by muse, mutect2
- HECTD2 | c.204G>A p.P68= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs373907920; called by muse, mutect2, varscan2
- HECTD4 | c.11211G>A p.L3737= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV66387137; called by muse, mutect2
- HMCN1 | c.237C>T p.F79= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as COSV99623387; called by muse, mutect2
- HMHB1 | c.43C>T p.L15= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as COSV99193126; called by muse, mutect2
- IDO1 | c.1098G>A p.K366= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99503129; called by muse, mutect2, varscan2
- IDO2 | c.990G>A p.L330= (on ENST00000389060; = p.L343= on NM_194294.2) | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1414781273, COSV100584487, COSV58423301; called by muse, mutect2
- KCNB2 | c.48G>A p.S16= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV73053445; called by muse, mutect2, varscan2
- KCTD10 | c.264C>T p.L88= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV57326546; called by muse, mutect2, varscan2
- KDM2B | c.615G>A p.Q205= | Silent (SNP) | VAF 26/250 reads (10%) | catalogued as COSV65646019; called by muse, mutect2, varscan2
- KDM5C | c.2955G>A p.E985= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs782405833, COSV64771276; called by muse, mutect2, varscan2
- KIF2B | c.1707C>T p.I569= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1412158931, COSV52136804; called by muse, mutect2, varscan2
- KLRC1 | c.21C>A p.I7= | Silent (SNP) | VAF 26/222 reads (12%) | catalogued as COSV100760718; called by muse, mutect2, varscan2
- LRRC8E | c.897C>T p.F299= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV60719491; called by muse, mutect2
- MADD | c.1272G>T p.L424= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV60630609; called by muse, mutect2, varscan2
- MAGEA8 | c.489G>A p.V163= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV99674350; called by muse, mutect2
- MIEF2 | c.1227C>T p.I409= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs749267118, COSV59902631; called by muse, mutect2, varscan2
- MUC16 | c.693G>C p.G231= | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV67502301, COSV67502516; called by muse, mutect2, varscan2
- NLRP12 | c.1701G>A p.L567= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV60757234; called by muse, mutect2, varscan2
- NOL10 | c.1293G>A p.Q431= | Silent (SNP) | VAF 25/296 reads (8%) | catalogued as COSV100629815; called by muse, mutect2
- NOMO1 | c.2610C>T p.F870= | Silent (SNP) | VAF 25/548 reads (5%) | catalogued as rs1471156588, COSV99814173; called by muse, mutect2
- NT5C3A | c.126G>A p.K42= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99640870; called by muse, mutect2, varscan2
- OR2B3 | c.393C>T p.H131= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV101013743; called by muse, mutect2
- OR8H1 | c.375C>T p.I125= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs752691732, COSV57293049, COSV57296335; called by muse, mutect2, varscan2
- PAPSS2 | c.630G>A p.L210= | Silent (SNP) | VAF 17/163 reads (10%) | catalogued as COSV63265480; called by muse, mutect2, varscan2
- PLEKHA7 | c.3327C>T p.L1109= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60581110; called by muse, mutect2, varscan2
- PNLDC1 | c.165C>A p.V55= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV51708841; called by muse, mutect2, varscan2
- PPP2R1A | c.1056C>G p.L352= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs749256759, COSV100436024; called by muse, mutect2, varscan2
- PPP3CA | c.570G>A p.L190= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV59932088; called by muse, mutect2
- PRKDC | c.1464C>T p.I488= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV100038171; called by muse, mutect2
- R3HDML | c.402C>T p.L134= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV53838159; called by muse, mutect2, varscan2
- RAB40AL | c.762C>G p.L254= | Silent (SNP) | VAF 21/228 reads (9%) | catalogued as rs141138772, COSV99504960; called by muse, mutect2
- RAVER2 | c.1069C>T p.L357= | Silent (SNP) | VAF 18/137 reads (13%) | catalogued as rs373293420; called by muse, mutect2, varscan2
- RPAP2 | c.1101T>G p.L367= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV72509717; called by muse, mutect2, varscan2
- SCAMP3 | c.9G>A p.Q3= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV56944960, COSV56947922; called by muse, mutect2, varscan2
- SF1 | c.1351C>T p.L451= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs907812330, COSV57118224; called by muse, mutect2, varscan2
- SIDT2 | c.366G>A p.K122= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs1316900012, COSV54057781, COSV54061744; called by muse, mutect2, varscan2
- SLC25A13 | c.90C>T p.N30= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs777148254, COSV55714861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A34 | c.232C>T p.L78= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV53818920; called by muse, mutect2, varscan2
- SPRTN | c.327C>G p.L109= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as rs149447916; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENT2 | c.390C>T p.V130= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV57139849; called by muse, mutect2, varscan2
- TMEM131 | c.3039C>T p.F1013= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as COSV99486358; called by muse, mutect2, varscan2
- TRIOBP | c.5032C>T p.L1678= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs557256047, COSV60385932; called by muse, mutect2, varscan2
- TRPM4 | c.1944C>G p.L648= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99418904; called by muse, mutect2
- UCP1 | c.273C>T p.L91= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV99530094; called by muse, mutect2
- UNC13A | c.363C>T p.I121= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV53214382; called by muse, mutect2, varscan2
- UNC13C | c.810C>G p.L270= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV52934367; called by muse, mutect2, varscan2
- USP49 | c.1800C>G p.L600= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV51901598, COSV99789820; called by muse, mutect2, varscan2
- VPS13B | c.6612G>A p.L2204= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV62159098; called by muse, mutect2, varscan2
- ZNF536 | c.2055C>A p.R685= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100834563; called by muse, mutect2
- ZNF550 | c.132C>G p.T44= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs1295479783, COSV100286351; called by muse, mutect2
- ZNF648 | c.1389C>T p.L463= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV60573133; called by muse, mutect2, varscan2
- CD300LD | chr17:74592522 G>A | 5'Flank (SNP) | VAF 12/88 reads (14%) | catalogued as rs764748120; called by muse, mutect2, varscan2
- MARF1 | chr16:15643354 G>T | 5'Flank (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100705582, COSV60020134; called by muse, mutect2
- MIR492 | n.91C>G | RNA (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- NTNG1 | c.1087+10916G>C | Intron (SNP) | VAF 30/215 reads (14%) | catalogued as COSV64280859; called by muse, mutect2, varscan2
- POM121 | chr7:72948894 G>A | 3'Flank (SNP) | VAF 9/59 reads (15%) | catalogued as COSV57510120; called by muse, mutect2, varscan2
- RPGR | c.2520+292G>A | Intron (SNP) | VAF 55/521 reads (11%) | catalogued as COSV58840973; called by muse, mutect2, varscan2
- SHMT2 | c.-1G>A | 5'UTR (SNP) | VAF 24/223 reads (11%) | catalogued as COSV100196942; called by muse, mutect2, varscan2
